Surgical pathology report (de-identified scan), TCGA case TCGA-HM-A3JJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-HM-A3JJ-01A (Primary Tumor).

[page 1 of 2]
Date Coll:

SURGICAL PATHOLOGY REPORT

SPECIMEN

- A. Uterus, cervix, peritoneum
- B. Right pelvic lymph node
- C. Right periaortic node
- D. Left pelvic lymph node
- E. Left periaortic node

ICD-0-3
carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9
lw 12/8/11

CLINICAL NOTES

PRE-OP DIAGNOSIS: Squamous cell carcinoma cervix, status post leep,
PET/CT.
PRE-OP DIAGNOSIS: Cervical cancer.

GROSS DESCRIPTION

A. Received fresh, subsequently fixed in formalin labelled "uterus, cervix, peritoneum." The specimen consists of 317 grams. The specimen is 11. 5 x 9.0 x 6.5 cm and partially covered with abundant paracervical parametrial tissue. The serosa of the specimen is pink-tan smooth glistening as is the ectocervix. The specimen has been previously opened up at the anterior wall showing a lush smooth endometrium with an average thickness of 0.7 cm. The endocervix is pink-tan and slightly trabeculated with a large firm mass measuring 3.0 x 2.5 x 0.8 cm on the anterior right side. This comes within 1.2 cm of the nearest margin which is anterior. The anterior half is inked blue. The posterior half is inked black. The myometrium is pink-tan and slightly trabeculated showing a 3.5 intramural fibroid which is white whorled and shows no gross evidence of hemorrhage or necrosis present. The average thickness of myometrium is 3.0 cm. Representative sections of the specimen are submitted as follows:

BLOCK SUMMARY: 1-2 - representative section of endometrium; 3 - right side parametrial tissue; 4 - left side parametrial tissue; 5 - representative section of fibroid; 6-8 - left paracervical tissue; 9-11 - right paracervical tissue; 12 - lower uterine segment cross-section; 13 - 9 o'clock cervix full thickness composite; 15, 16 - 10 o'clock cervix full thickness composite; 17 - full thickness slice; 18 and 19 - 12 o'clock full thickness slice; 20, 21 - 2 o'clock full thickness composite; 22 and 23 - 6 o'clock full thickness composite. RS-23

Representative sections of the cervix will be submitted following further fixation.

B. Received fresh labeled "right pelvic lymph node" is a 4.8 x 4.3 x 1.6 cm aggregate of fragmented, soft tan-gold adipose tissue. Several soft to slightly rubbery tan-pink-red tissues in keeping with lymph nodes measuring up to 7.6 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in four blocks as labeled. RS-4.

BLOCK SUMMARY: 1 - Seven whole lymph nodes; 2-4 - largest lymph node.

C. Received fresh labeled "right periaortic node" are two slightly rubbery tan-pink tissues in keeping with lymph nodes averaging 1.2 cm in greatest dimension admixed with a scant

[page 2 of 2]
amount of adipose tissue. The specimens are submitted in toto in one block. AS-1 (two whole lymph nodes).

D. Received fresh labeled "left pelvic lymph node" is a 4.8 x 4.4 x 1.6 cm aggregate of soft, lobulated golden-yellow adipose tissue. Several soft tan-white to tan-pink tissues in keeping with lymph nodes measuring up to 2.9 cm in greatest dimension are recovered. The lymphoid tissues are entirely submitted in six blocks. RS-6.

BLOCK SUMMARY: 1 - Four whole nodes; 2 - three whole nodes; 3-6 - one bisected node per cassette.

E. Received fresh labeled "left periaortic node" are two slightly rubbery tan-pink tissues in keeping with lymph nodes measuring up to 1.2 cm with a scant amount of associated adipose tissue. Specimen is entirely submitted in three blocks as labeled. AS-3.

MICROSCOPIC DESCRIPTION

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly-differentiated, with necrosis.

Primary tumor (pT)TNM(FIGO): 3.0 x 2.5 x 1.2 cm mass, extending into lower uterine segment, and with positive paracervical lymph nodes.

Greatest depth of invasion: 1.2 cm

Margins of resection: Negative

Vascular invasion: Present, extensive

Regional lymph nodes (pN):

A. Carcinoma present in one right paracervical tissue lymph node and one posterior (6:00) paracervical tissue lymph node (2/2)

B. Right pelvic nodes: twenty-three negative lymph nodes (0/23)

C. Right periaortic nodes: two negative lymph nodes (0/2)

D. Left pelvic nodes: two of eleven lymph nodes with carcinoma (2/11)

E. Left periaortic nodes: three negative lymph nodes (0/3)

Other findings: secretory endometrium with polyps; no hyperplasia. Adenomyosis, leiomyoma.

Comment: portions of this case also reviewed by

5, 4x4

DIAGNOSIS

A. Uterus, hysterectomy:

Squamous cell carcinoma of the cervix, poorly-differentiated, almost circumferentially involving the cervix and extending into the lower uterine segment.

Size: 3.0 x 2.5 x 1.2 cm (greatest depth of invasion 1.2 cm).

Two paracervical tissue lymph nodes with metastatic carcinoma (2/2).

Negative margins of excision.

B. Lymph nodes, right pelvic, regional resection:

Twenty-three negative lymph nodes (0/23).

C. Lymph nodes, right periaortic, regional resection:

Two negative lymph nodes (0/2).

D. Lymph nodes, left pelvic, regional resection:

Two of eleven lymph nodes with metastatic carcinoma (2/11).

E. Lymph nodes, left periaortic, regional resection:

Three negative lymph nodes (0/3).

MD (Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file ad90afdd-bdf9-4dff-97fc-f0b7bd6b51e6 (TCGA-HM-A3JJ.5F8358A7-34EB-4DAA-81F0-18B27BDCDF65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).